Surgical pathology report (de-identified scan), TCGA case TCGA-DQ-7591, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Of Michigan, specimen TCGA-DQ-7591-01A (Primary Tumor).

SP FINAL REPORT Source:

HISTORY:

History of left neck mass, which on CT showed a mass at the left base of tongue with left neck adenopathy. Stain for p-16, EGFR and HPV.

GROSS:

1. "Left base of tongue" Received in formalin in a small container is a 0.6 x 0.7 cm irregular portions of pink-tan soft tissue.

MICROSCOPIC DIAGNOSIS:

1. Left base of tongue, biopsy: Invasive, poorly-differentiated, nonkeratinizing squamous cell carcinoma. See COMMENT.

COMMENT

The tumor is diffusely and strongly positive for P16 and EGFR. In situ hybridization for high-risk HPV is positive.

I, [REDACTED] and [REDACTED], the signing staff pathologist, have personally examined and interpreted the slides from this case.

"This test was developed and its performance characteristics determined by the [REDACTED]. It has not been cleared or approved by the U.S. Food and Drug Administration. (The FDA has determined that such clearance is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ['CLIA'] as qualified to perform high complexity testing)."

Close

Source: NCI Genomic Data Commons file 89437623-9c6f-46b0-835d-f53e706548b0 (TCGA-DQ-7591.0CCAE762-78D9-4273-9D99-F431085F22DD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).